FM case AD5926 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/bde7e012-e81d-41c8-9cf8-8b48a0e3143b

Male, 53.2 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the lung. Sample type: Tumor.
